Somatic mutation profile of tumor specimen 0DI6L1 from CCDI case PBBVHR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.9 years (3,598 days).
Specimen 0DI6L1: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11da0ec3-a17c-47ca-8048-b7135e0fd79d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI6KL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64e6784a-6e8d-4c36-8e39-94e5b01b194f

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AK9 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 41/1101 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV58138852; called by muse, mutect2
- GALNT18 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 377/794 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs376689514; called by muse, mutect2, varscan2
- MYO15A | c.9883C>T p.R3295C | Missense Mutation (SNP) | VAF 157/1041 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775389608, COSV52755815; called by muse, mutect2, varscan2
- NEDD4L | c.1972C>A p.L658I (on ENST00000400345 / NM_001144967.3; = p.L638I on NM_015277.6) | Missense Mutation (SNP) | VAF 67/594 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99896251; called by muse, mutect2, varscan2
- TCEANC2 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 227/774 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs142956141; called by muse, mutect2, varscan2
- C14orf28 | c.386T>G p.I129S | Missense Mutation (SNP) | VAF 31/674 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CD22 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 68/500 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.28); called by mutect2, varscan2
- CRYBG3 | c.3842C>T p.P1281L | Missense Mutation (SNP) | VAF 30/763 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, mutect2
- CYP1A2 | c.508A>C p.K170Q | Missense Mutation (SNP) | VAF 97/713 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GSG1L | c.895G>A p.A299T (on ENST00000447459 / NM_001109763.2; = p.A144T on NM_144675.2) | Missense Mutation (SNP) | VAF 26/834 reads (3%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); called by muse, mutect2
- OR10AC1 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 107/1048 reads (10%) | SIFT tolerated, low confidence (0.88); called by muse, mutect2, varscan2
- TP53BP2 | c.1535C>T p.P512L (on ENST00000343537 / NM_001031685.3; = p.P383L on NM_005426.2) | Missense Mutation (SNP) | VAF 259/824 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- YTHDC1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 154/447 reads (34%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.026); called by mutect2, varscan2
- AK9 | c.1590T>A p.A530= | Silent (SNP) | VAF 56/990 reads (6%) | called by muse, mutect2
- RIBC2 | c.351G>C p.L117= | Silent (SNP) | VAF 56/1158 reads (5%) | called by muse, mutect2
- SPANXN5 | c.72T>C p.D24= | Silent (SNP) | VAF 30/350 reads (9%) | called by muse, mutect2
- CALM3 | c.-27C>G | 5'UTR (SNP) | VAF 34/645 reads (5%) | catalogued as rs991763156; called by muse, mutect2
- SPINT2 | c.338-79G>A | Intron (SNP) | VAF 8/168 reads (5%) | catalogued as rs910334084; called by muse, mutect2
